HCMI case HCM-BROD-0004-C64 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/63653137-c694-4ad6-83a3-eaaff1df2ca7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 2008; Vital status: Alive.

Diagnoses (1)
1. Nephroblastoma, NOS: ICD-O-3 morphology code: 8960/3; ICD-10 code: C64.9; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 3.6 years (1,329 days); Metastasis at diagnosis: No Metastasis; Prior malignancy: yes; Prior treatment: No; COG renal stage: Stage II; Wilms tumor histologic subtype: Favorable.
   Pathology details: Anaplasia present: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Ifosfamide + Vincristine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: VDC/IE; Days to treatment start: 610 days (1.7 years); Days to treatment end: 625 days (1.7 years).
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 610 days (1.7 years); Days to treatment end: 625 days (1.7 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 625 days (1.7 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 610.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 16.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Cancer.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-BROD-0004-C64-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample HCM-BROD-0004-C64-11B: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-BROD-0004-C64-11B-01-S1-HE: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 80; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide HCM-BROD-0004-C64-11B-01-S2-HE: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 80; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
- Sample HCM-BROD-0004-C64-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 2D Modified Conditionally Reprogrammed Cells; Preservation method: Frozen; Passage count: 14.
- Samples HCM-BROD-0004-C64-85R, HCM-BROD-0004-C64-85S (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 20.
